Somatic mutation profile of tumor specimen TCGA-SW-A7EB-01A (aliquot TCGA-SW-A7EB-01A-11D-A34U-08) from TCGA case TCGA-SW-A7EB, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 45.1 years (16,475 days).
Specimen TCGA-SW-A7EB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40578b76-37fa-4e66-8f89-cece9010d5b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SW-A7EB-10A (Blood Derived Normal), aliquot TCGA-SW-A7EB-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/062ee9fd-798f-4bf7-a042-a738177e33fc

The open-access MAF lists 138 somatic variants for this specimen: 109 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 27, Nonsense Mutation 9, Frame Shift Ins 2, Intron 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | hotspot (GDC flag); catalogued as CM971503, COSV52676850, COSV52715987, COSV52740951; called by muse, mutect2, varscan2
- ABCG1 | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as rs1442478823, COSV100494087; called by muse, mutect2, varscan2
- ACOX3 | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149218868; called by muse, mutect2, varscan2
- ACTN4 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99400682; called by muse, mutect2, varscan2
- AGAP3 | c.698C>T p.T233I (on ENST00000622464; = p.T269I on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58996041; called by muse, mutect2, varscan2
- ANGPTL2 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs780586834, COSV99402463; called by muse, mutect2, varscan2
- APAF1 | c.1181A>C p.K394T (on ENST00000551964 / NM_181861.2; = p.K383T on NM_001160.3) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV100244392; called by muse, mutect2, varscan2
- ASH1L | c.4786G>C p.E1596Q | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); catalogued as COSV100853578; called by muse, mutect2, varscan2
- ATP1A1 | c.2094G>T p.K698N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99814736; called by muse, mutect2, varscan2
- ATXN7 | c.1810G>A p.V604I | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV99895199; called by muse, mutect2
- BCLAF1 | c.509A>G p.E170G | Missense Mutation (SNP) | VAF 14/271 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV100786936; called by muse, mutect2
- BICD1 | c.2052A>C p.K684N | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99862901; called by muse, mutect2
- C6orf118 | c.1233dup p.E412Rfs*3 | Frame Shift Ins (INS) | VAF 18/147 reads (12%) | catalogued as rs747936548; called by mutect2, pindel, varscan2
- CACNB2 | c.1639C>A p.R547S (on ENST00000324631 / NM_201596.3; = p.R492S on NM_000724.4) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774654438, COSV56648945, COSV99996155; called by muse, mutect2, varscan2
- CCR3 | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as COSV100656740, COSV62463212; called by muse, mutect2
- CFAP57 | c.1661C>G p.S554C | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV100994069; called by muse, mutect2
- CFHR5 | c.440G>C p.C147S | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99889570; called by muse, mutect2
- CIT | c.983C>A p.P328H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as COSV99950757; called by muse, mutect2, varscan2
- CLEC16A | c.2174G>A p.R725Q | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as rs200931583, COSV55488636; called by muse, mutect2
- CNTNAP2 | c.2441C>G p.T814S | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as COSV100671075; called by muse, mutect2, varscan2
- COL6A3 | c.5391C>G p.F1797L | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV55099860, COSV99800872; called by muse, mutect2, varscan2
- DCLK1 | c.783G>T p.E261D | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV99712793; called by muse, mutect2, varscan2
- DISC1 | c.561C>A p.C187* | Nonsense Mutation (SNP) | VAF 6/82 reads (7%) | catalogued as COSV99698500; called by muse, mutect2
- DMPK | c.1079G>A p.G360D | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.874); catalogued as COSV99353625; called by muse, mutect2, varscan2
- DNAH11 | c.13088C>G p.T4363S | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.272); catalogued as COSV100180549; called by muse, mutect2, varscan2
- DPYSL5 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs916856911, COSV56515890; called by muse, mutect2, varscan2
- FAM234A | c.440C>A p.T147K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs770280178, COSV100056407; called by muse, mutect2, varscan2
- GCSAM | c.190A>G p.N64D | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.098); catalogued as COSV100453354; called by muse, mutect2, varscan2
- GJA4 | c.360C>A p.D120E | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.034); catalogued as COSV100654734; called by muse, mutect2
- GKN1 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV100933574, COSV65006917; called by muse, mutect2, varscan2
- GPC6 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.694); catalogued as rs756656699, COSV65524625; called by muse, mutect2, varscan2
- GPR183 | c.315G>C p.R105S | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100854383; called by muse, mutect2, varscan2
- GRM5 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1296844806, COSV100554201; called by muse, mutect2, varscan2
- GSAP | c.1291C>T p.H431Y | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99990476; called by muse, mutect2, varscan2
- HEATR1 | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100857227; called by muse, mutect2, varscan2
- HEPACAM2 | c.781G>C p.D261H (on ENST00000394468 / NM_001039372.4; = p.D249H on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV100506757; called by muse, mutect2, varscan2
- HMCN1 | c.11383C>T p.R3795* | Nonsense Mutation (SNP) | VAF 30/144 reads (21%) | catalogued as rs150673369, COSV54878020; called by muse, mutect2, varscan2
- IFI44L | c.815C>A p.A272E | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV100655097; called by muse, mutect2, varscan2
- IGSF9 | c.593G>C p.R198P | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV63639034, COSV63639533; called by mutect2, varscan2
- KARS1 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | catalogued as COSV100094468; called by muse, mutect2, varscan2
- KRT2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748975311, COSV59011699; called by muse, mutect2, varscan2
- LRFN5 | c.899A>G p.E300G | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99985237; called by muse, mutect2, varscan2
- LRRC8C | c.1183G>C p.V395L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV100968395; called by muse, mutect2, varscan2
- M1AP | c.599G>C p.S200T | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.168); catalogued as COSV99304476; called by muse, mutect2, varscan2
- MDP1 | c.454C>G p.Q152E | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99164576, COSV99164584; called by muse, mutect2, varscan2
- METTL15 | c.440G>T p.S147I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1407003290, COSV100328717; called by muse, mutect2, varscan2
- MGAT3 | c.19A>T p.K7* | Nonsense Mutation (SNP) | VAF 16/136 reads (12%) | catalogued as COSV100362052; called by muse, mutect2, varscan2
- MGLL | c.275A>C p.D92A (on ENST00000398104 / NM_001003794.2; = p.D102A on NM_007283.6) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as COSV99412305; called by muse, mutect2, varscan2
- MLPH | c.995G>C p.R332T | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as COSV99222594; called by muse, mutect2
- MRAS | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56675173; called by muse, mutect2, varscan2
- MRGPRX3 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.746); catalogued as rs773230791, COSV101283576; called by muse, mutect2, varscan2
- MYH1 | c.5116G>A p.A1706T | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as rs779544532, COSV56845883; called by muse, mutect2, varscan2
- MYH13 | c.2272G>C p.E758Q | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as COSV99355213; called by muse, mutect2
- NAGA | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM078422, COSV101124174, COSV101124176; called by muse, mutect2
- NAXD | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.887); catalogued as rs1266072991, COSV100010656; called by muse, mutect2, varscan2
- NCAM2 | c.226T>A p.S76T | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53093462; called by muse, mutect2
- NLRP2 | c.1992G>C p.E664D | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as COSV99672598; called by muse, mutect2, varscan2
- OR10A7 | c.645G>T p.L215F | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as COSV100406627; called by muse, mutect2, varscan2
- OR5K2 | c.898G>T p.V300F | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV101415979; called by muse, mutect2, varscan2
- OR6S1 | c.10G>C p.D4H | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as COSV100289503; called by muse, mutect2, varscan2
- OTOF | c.2663C>T p.T888M (on ENST00000272371 / NM_194248.3; = p.T141M on NM_004802.4) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs766595357, COSV99716629, COSV99718786; called by muse, mutect2, varscan2
- PAPOLB | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.071); catalogued as rs759171720, COSV68201331; called by muse, mutect2
- PHF3 | c.3639C>G p.I1213M | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100013853; called by muse, mutect2, varscan2
- PLA2G4A | c.251A>C p.E84A | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.181); catalogued as COSV100820697; called by muse, mutect2, varscan2
- POP7 | c.106G>C p.D36H | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100292190, COSV57450000; called by muse, mutect2, varscan2
- PPM1D | c.1372C>T p.R458* | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as rs773389405, CM137522, COSV59954743; called by muse, mutect2, varscan2
- PSPC1 | c.434G>C p.R145T | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100142611; called by muse, mutect2, varscan2
- PTDSS1 | c.641G>A p.W214* | Nonsense Mutation (SNP) | VAF 23/266 reads (9%) | catalogued as COSV100428898; called by muse, mutect2
- PTPRN | c.2679G>C p.K893N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99834270; called by muse, mutect2, varscan2
- RARA | c.650G>C p.R217P | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV54195958, COSV99565369; called by muse, mutect2, varscan2
- RBM15 | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV100873500; called by muse, mutect2, varscan2
- RBM39 | c.669C>G p.I223M | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53615316, COSV99488857; called by muse, mutect2
- RGS12 | c.4145C>G p.P1382R (on ENST00000336727; = p.P734R on NM_198227.2) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100123281, COSV100123402; called by muse, mutect2, varscan2
- RNF31 | c.2107G>A p.G703S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as COSV53761442, COSV99396263; called by muse, mutect2
- SCEL | c.44-2A>G p.X15_splice | Splice Site (SNP) | VAF 51/258 reads (20%) | catalogued as COSV100583180; called by muse, mutect2, varscan2
- SFMBT2 | c.2021C>A p.P674H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100739567; called by muse, mutect2, varscan2
- SFMBT2 | c.1716C>G p.I572M | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100739568, COSV62811279; called by muse, mutect2, varscan2
- SLC10A6 | c.895A>T p.I299L | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99907370; called by muse, mutect2
- SLC6A1 | c.859G>C p.D287H | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99823144; called by muse, mutect2
- SLC6A15 | c.64G>T p.D22Y | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57019932, COSV57030277, COSV99881438; called by muse, mutect2, varscan2
- SMARCA4 | c.3557C>T p.A1186V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV60788639, COSV60811013; called by muse, mutect2, varscan2
- SMC2 | c.1443G>C p.K481N | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV53963103, COSV99659594; called by muse, mutect2
- SORBS1 | c.2281C>T p.H761Y (on ENST00000361941 / NM_001034954.2; = p.H508Y on NM_024991.3 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99528823; called by muse, mutect2
- SPAG1 | c.193C>A p.L65I | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.067); catalogued as COSV99309407; called by muse, mutect2, varscan2
- SPTBN2 | c.4438C>T p.R1480C | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113974204, COSV59447719; called by muse, mutect2, varscan2
- STAB2 | c.5875T>A p.C1959S | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV101186263; called by muse, mutect2
- SYNE1 | c.19786C>G p.Q6596E (on ENST00000367255 / NM_182961.4; = p.Q6525E on NM_033071.3) | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); catalogued as COSV99576307; called by muse, mutect2
- TAC1 | c.173G>C p.R58T | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100071192, COSV100071211; called by muse, mutect2
- TBC1D4 | c.1459C>G p.L487V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100884775; called by muse, mutect2, varscan2
- TECTA | c.3639T>G p.F1213L | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV99881323; called by muse, mutect2, varscan2
- TEX35 | c.455C>A p.A152E | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.279); catalogued as COSV99274917; called by muse, mutect2, varscan2
- TMEM71 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.102); catalogued as rs369527509, COSV63458279; called by muse, mutect2, varscan2
- TMF1 | c.3148C>G p.Q1050E | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV101275458, COSV68376035; called by muse, mutect2
- TOB1 | c.628G>C p.G210R | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99278941; called by muse, mutect2, varscan2
- TRIM9 | c.1580C>A p.T527N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as rs775523243, COSV100032127; called by muse, mutect2, varscan2
- TRPV5 | c.1847C>G p.S616C | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs771893419, COSV99520959; called by muse, mutect2
- TSHZ3 | c.2317A>T p.K773* | Nonsense Mutation (SNP) | VAF 14/76 reads (18%) | catalogued as COSV53665723, COSV99552535; called by muse, mutect2, varscan2
- TSPAN3 | c.262A>T p.I88F | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV99144471; called by muse, mutect2, varscan2
- TTN | c.4414C>A p.Q1472K (on ENST00000591111; = p.Q1426K on NM_003319.4) | Missense Mutation (SNP) | VAF 11/93 reads (12%) | PolyPhen probably damaging (0.979); catalogued as COSV100627055; called by muse, mutect2, varscan2
- TUBD1 | c.926T>A p.M309K | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as COSV100360249; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3368T>G p.L1123W | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV99692067; called by muse, mutect2, varscan2
- WDR35 | c.1649C>G p.S550C (on ENST00000345530 / NM_001006657.2; = p.S539C on NM_020779.4) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV99853473; called by muse, mutect2, varscan2
- XKR4 | c.1946C>G p.T649S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.985); catalogued as COSV59312479; called by muse, mutect2
- ZFP36 | c.419G>C p.R140P (on ENST00000594442; = p.R134P on NM_003407.5) | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99953970; called by muse, mutect2
- ZNF454 | c.802G>T p.G268* | Nonsense Mutation (SNP) | VAF 4/52 reads (8%) | catalogued as COSV100195315, COSV60768513; called by muse, mutect2
- ZNF577 | c.951G>C p.Q317H | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV100031243; called by muse, mutect2
- EMILIN2 | c.1696G>A p.G566S | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2
- TRAV9-1 | c.223A>C p.K75Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- WDR11 | c.600dup p.V201Sfs*9 | Frame Shift Ins (INS) | VAF 32/138 reads (23%) | called by mutect2, pindel, varscan2
- ABCA12 | c.2172C>A p.T724= (on ENST00000272895 / NM_173076.3; = p.T406= on NM_015657.3) | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV99791682; called by muse, mutect2
- ACSL6 | c.543G>C p.L181= (on ENST00000379240; = p.L206= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/127 reads (9%) | catalogued as COSV99734532; called by muse, mutect2
- ANO4 | c.1137G>A p.L379= (on ENST00000392977 / NM_001286615.2; = p.L344= on NM_178826.4) | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as COSV100153639; called by muse, mutect2
- CEMIP | c.924C>T p.G308= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs1007177974, COSV54994715; called by muse, mutect2
- CXXC5 | c.510G>A p.E170= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV100210804; called by muse, mutect2, varscan2
- DOCK10 | c.6066G>A p.S2022= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs1205980654, COSV99291298; called by muse, mutect2, varscan2
- H2BC7 | c.279G>A p.R93= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as COSV100587265; called by muse, mutect2, varscan2
- HIC2 | c.1452C>T p.A484= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs759072083, COSV68041883; called by muse, mutect2, varscan2
- HLX | c.1056A>G p.S352= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100854613; called by muse, mutect2
- ITGA7 | c.1275C>T p.F425= (on ENST00000555728; = p.F381= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs774888135, COSV57696209, COSV57703438; called by muse, mutect2, varscan2
- ITGB3 | c.2253A>G p.K751= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV101457665; called by muse, mutect2
- KCNN2 | c.930A>C p.P310= (on ENST00000264773; = p.P522= on NM_021614.4) | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as COSV99300613; called by muse, mutect2, varscan2
- LRRIQ1 | c.5058T>C p.F1686= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV101280692; called by muse, mutect2, varscan2
- LYST | c.7104T>C p.D2368= | Silent (SNP) | VAF 26/227 reads (11%) | catalogued as COSV101090157; called by muse, mutect2, varscan2
- MDGA2 | c.1848G>A p.L616= (on ENST00000399232 / NM_001113498.2; = p.L318= on NM_182830.4) | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV100638247, COSV62100887; called by muse, mutect2, varscan2
- OR9G1 | c.300C>T p.F100= | Silent (SNP) | VAF 8/134 reads (6%) | catalogued as rs1281226347, COSV100380539, COSV56449371; called by muse, mutect2
- PATJ | c.5265C>A p.I1755= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs1247322890, COSV100957606; called by muse, mutect2, varscan2
- RP1 | c.528C>T p.V176= | Silent (SNP) | VAF 8/136 reads (6%) | catalogued as COSV99608627; called by muse, mutect2
- SGO2 | c.3762T>C p.F1254= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as rs536387333, COSV100764786; called by muse, mutect2, varscan2
- SLC10A6 | c.894G>A p.L298= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV99907371; called by muse, mutect2
- SLC17A9 | c.684C>T p.N228= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1324834805, COSV100947985; called by muse, mutect2, varscan2
- SLC26A6 | c.132G>A p.L44= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as COSV99374758; called by muse, mutect2, varscan2
- SORBS1 | c.2280C>G p.R760= (on ENST00000361941 / NM_001034954.2; = p.R507= on NM_024991.3 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV53353555, COSV99528825; called by muse, mutect2
- SPPL2C | c.1164C>T p.F388= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs1305128282, COSV100234137, COSV61292172; called by muse, mutect2, varscan2
- TENM2 | c.1626G>A p.Q542= (on ENST00000518659 / NM_001122679.2; = p.Q310= on NM_001080428.3) | Silent (SNP) | VAF 9/111 reads (8%) | catalogued as COSV101319381; called by muse, mutect2
- TLL2 | c.2907C>T p.G969= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100780481; called by muse, mutect2
- ZNF549 | c.1368C>T p.R456= (on ENST00000376233 / NM_001199295.2; = p.R443= on NM_153263.2) | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV99558745; called by muse, mutect2, varscan2
- ERCC6 | c.1397+7013_1397+7021del | Intron (DEL) | VAF 23/137 reads (17%) | called by mutect2, pindel, varscan2
- VPS26C | chr21:37221492 C>G | 3'Flank (SNP) | VAF 16/163 reads (10%) | called by muse, mutect2
